Somatic mutation profile of tumor specimen HCM-CSHL-0377-C18-01A (aliquot HCM-CSHL-0377-C18-01A-11D-A78T-36) from HCMI case HCM-CSHL-0377-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 69.7 years (25,463 days).
Specimen HCM-CSHL-0377-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b0b818e-aca8-4985-821e-aed791545597.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0377-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0377-C18-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdc66f42-b1ba-46dd-8baa-1afeb7578ef4

The open-access MAF lists 1,064 somatic variants for this specimen: 693 protein-altering or splice-affecting, 248 silent, 123 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 604, Silent 248, Intron 58, Frame Shift Del 35, 5'UTR 27, Nonsense Mutation 21, Splice Site 17, 3'UTR 16, Splice Region 12, 5'Flank 9, RNA 9, 3'Flank 4.

Variants (750 of 1,064; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FKRP | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1247934219, CM073068, CM074872; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- FLNC | c.4871C>T p.S1624L | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs879255639, CM162118, COSV100369004; ClinVar: pathogenic; called by muse, mutect2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SPTA1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918642, CM910358, CM910359, COSV63752484; ClinVar: pathogenic; called by muse, mutect2
- AASDH | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1226649602, COSV52704333; called by muse, mutect2
- ABCC1 | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778697425, COSV60686300; called by muse, mutect2
- ABRAXAS1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs549027065; called by muse, mutect2
- ACACB | c.761T>C p.F254S | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.501); catalogued as rs768750072; called by muse, mutect2
- ADAM10 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 35/655 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs747308486; called by muse, mutect2
- ADGRA1 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 29/458 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs906519509; called by muse, mutect2
- ADGRL2 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54679818; called by muse, mutect2
- ALPG | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 37/501 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs150811092; called by muse, mutect2
- ANOS1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs372392838, COSV52920966; called by muse, mutect2, varscan2
- AQP8 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 29/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762948461, COSV54845261; called by muse, mutect2
- ARHGAP4 | c.499-4G>A | Splice Region (SNP) | VAF 14/136 reads (10%) | catalogued as rs1341642627; called by muse, mutect2, varscan2
- ARHGEF17 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs892543833; called by muse, mutect2
- ARHGEF17 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1038055507; called by muse, mutect2
- ARID2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.061); catalogued as rs980692773, COSV57614718; called by muse, mutect2
- ASPM | c.4592G>A p.R1531H | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200681905, COSV54139741, COSV99660913; called by muse, mutect2
- ATP8B4 | c.1676C>A p.S559Y | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV99464129; called by muse, mutect2
- AUTS2 | c.2759A>G p.D920G | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV61420072; called by muse, mutect2
- B3GNT7 | c.1108A>G p.M370V | Missense Mutation (SNP) | VAF 48/529 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs760569261; called by muse, mutect2
- BACH2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs767734937, COSV57590949; called by muse, mutect2
- BAZ2B | c.4547C>T p.T1516M | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as rs1444509662, COSV58607797; called by muse, mutect2
- BCORL1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs1373179389, COSV54398446; called by muse, mutect2, varscan2
- C12orf42 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 31/428 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372316015, COSV59387580; called by muse, mutect2
- C1R | c.1655G>A p.R552H (on ENST00000536053 / NM_001354346.2; = p.R538H on NM_001733.7) | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1334659221, COSV101605620; called by muse, mutect2, varscan2
- C5AR1 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as rs138808390; called by muse, mutect2, varscan2
- C8B | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 26/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs138837336; called by muse, mutect2
- CACHD1 | c.1725A>G p.I575M | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51560386; called by muse, mutect2, varscan2
- CACNA1I | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1016081416; called by muse, mutect2
- CACNA1S | c.3823G>A p.V1275I | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.514); catalogued as rs760441649; called by muse, mutect2
- CASKIN1 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV58877343; called by muse, mutect2, varscan2
- CATSPERD | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 44/600 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200349808, COSV100486725; called by muse, mutect2
- CCDC178 | c.1895del p.K632Rfs*9 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | catalogued as COSV55780370; called by mutect2, varscan2
- CCDC22 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs782487743; called by muse, mutect2, varscan2
- CCDC51 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs371682973; called by muse, mutect2
- CDK2 | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57187628; called by muse, mutect2
- CDK4 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 52/910 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs876660318; ClinVar: uncertain significance; called by muse, mutect2
- CDK5R2 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV56935990; called by muse, mutect2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1325731082; called by pindel, varscan2
- CEP290 | c.4195-3del | Splice Region (DEL) | VAF 8/54 reads (15%) | catalogued as rs748771739; called by mutect2, pindel
- CFAP65 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs772103989, COSV58562929; called by muse, mutect2
- CHD3 | c.5521G>A p.E1841K (on ENST00000330494 / NM_001005273.3; = p.E1807K on NM_005852.4) | Missense Mutation (SNP) | VAF 32/493 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1313938382; called by muse, mutect2
- CHST12 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1175565150, COSV51676768; called by muse, mutect2
- CHST3 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 62/754 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64150890; called by muse, mutect2
- CHST8 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as COSV52857826; called by muse, mutect2
- CHUK | c.1569+1G>A p.X523_splice | Splice Site (SNP) | VAF 8/232 reads (3%) | catalogued as COSV64918273; called by muse, mutect2
- CILP | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.645); catalogued as rs771666368, COSV56022097; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs752250702; called by mutect2, varscan2
- CLASRP | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); catalogued as COSV55518602; called by muse, mutect2
- CLK2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 38/600 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); catalogued as rs201974382; called by muse, mutect2
- CNN2 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 38/535 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs116408565; called by muse, mutect2
- CNNM1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV63203024; called by muse, mutect2
- CSF2RB | c.2684A>C p.E895A | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV99453422; called by muse, mutect2, varscan2
- CST7 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs774561103, COSV65195674; called by muse, mutect2
- CTBP1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs371355192, COSV99337691; called by muse, mutect2
- CUX2 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400410114, COSV55624216; called by muse, mutect2
- CYB5R2 | c.633G>A p.W211* | Nonsense Mutation (SNP) | VAF 24/240 reads (10%) | catalogued as rs1382487716; called by muse, mutect2
- CYP2D7 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.683); catalogued as rs778324262; called by muse, mutect2
- DAB2IP | c.1238G>A p.R413Q (on ENST00000408936; = p.R385Q on NM_032552.3) | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1490540211; called by muse, mutect2
- DCLK1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs760301962, COSV55184477; called by muse, mutect2
- DCLK2 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as rs759398144, CM151902; called by muse, mutect2
- DDX11 | c.2271+5G>A | Splice Region (SNP) | VAF 36/570 reads (6%) | catalogued as rs199779676; called by muse, mutect2
- DIAPH3 | c.771+2T>C p.X257_splice | Splice Site (SNP) | VAF 9/195 reads (5%) | catalogued as COSV57369431; called by muse, mutect2
- DLEU7 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1310077935; called by muse, mutect2
- DNAH10 | c.9320G>A p.R3107H (on ENST00000409039; = p.R3046H on NM_207437.3) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1276943171, COSV101292571; called by muse, mutect2, varscan2
- DNAH2 | c.1689+1G>A p.X563_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV50014370; called by mutect2, varscan2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 28/688 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2
- DNAI1 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV54279422; called by muse, mutect2
- DOP1B | c.5812C>T p.R1938C | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs536538834, COSV101214937; called by muse, mutect2
- DOT1L | c.2806+6G>A | Splice Region (SNP) | VAF 36/390 reads (9%) | catalogued as rs535777073; called by muse, mutect2
- DST | c.20495C>T p.A6832V (on ENST00000361203 / NM_001374722.1; = p.A4529V on NM_015548.5) | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs748051176, COSV55009833; called by muse, mutect2, varscan2
- DUOX2 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 46/702 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs573487375, COSV101199756; called by muse, mutect2
- DUSP5 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 37/541 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1160733626; called by muse, mutect2
- DVL1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1375565508; called by muse, mutect2, varscan2
- EBF1 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1432710801; called by muse, mutect2
- EBLN1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1015265877; called by muse, mutect2
- EIF2S2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 18/376 reads (5%) | catalogued as COSV66621144; called by muse, mutect2
- EIPR1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as rs865933981; called by muse, mutect2
- ELAC2 | c.245+2T>G p.X82_splice | Splice Site (SNP) | VAF 24/370 reads (6%) | catalogued as rs748684065; called by muse, mutect2
- EOMES | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746252799; called by muse, mutect2
- EPAS1 | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 43/623 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1170479651; called by muse, mutect2
- ERCC5 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 36/374 reads (10%) | catalogued as CM025986; called by muse, mutect2
- EXT2 | c.1225G>A p.A409T (on ENST00000343631; = p.A442T on NM_000401.3) | Missense Mutation (SNP) | VAF 44/621 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100640718; called by muse, mutect2
- F2RL3 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 52/767 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs746738735; called by muse, mutect2
- FAH | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 33/709 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV99930567; called by muse, mutect2
- FAM209B | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 33/618 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.289); catalogued as COSV64915257; called by muse, mutect2
- FAM210B | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs748008152; called by muse, mutect2
- FAM234A | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs375399489; called by muse, mutect2
- FAM47C | c.2003del p.P668Rfs*157 | Frame Shift Del (DEL) | VAF 32/285 reads (11%) | catalogued as COSV63729354; called by mutect2, pindel, varscan2
- FANCL | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52078460; called by muse, mutect2
- FASN | c.2305-1G>T p.X769_splice | Splice Site (SNP) | VAF 43/707 reads (6%) | catalogued as COSV60759913; called by muse, mutect2
- FAT1 | c.4790T>C p.V1597A | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV101499113; called by muse, mutect2
- FBN1 | c.6845G>A p.R2282Q | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); catalogued as rs759696323; ClinVar: uncertain significance; called by muse, mutect2
- FBXL20 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52901883; called by muse, mutect2
- FEV | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55386546; called by muse, mutect2
- FEZF2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV51863369; called by muse, mutect2
- FGF23 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 56/860 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV52976418; called by muse, mutect2
- FGF3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 33/849 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as rs782297586; called by muse, mutect2
- FLNC | c.7171C>T p.H2391Y | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1554401558, COSV100368832; ClinVar: uncertain significance; called by muse, mutect2
- FLRT2 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV100420698; called by muse, mutect2
- FLVCR2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 59/726 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs772508772, COSV53163538; called by muse, mutect2
- FN1 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 38/608 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs761729774, COSV60550427; called by muse, mutect2
- FOXK1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1003844502, COSV61068538; called by muse, mutect2
- FUT8 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs762317080; called by muse, mutect2
- FZD1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1563008272, COSV55312341; called by muse, mutect2
- G6PC | c.764C>T p.T255I | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as CM023374, COSV53832342; called by muse, mutect2
- GABRA4 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs779696522; called by muse, mutect2
- GATA3 | c.708del p.S237Afs*28 | Frame Shift Del (DEL) | VAF 19/186 reads (10%) | catalogued as rs771019738, COSV60522496; called by mutect2, pindel, varscan2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 36/224 reads (16%) | catalogued as rs761897305; called by mutect2, varscan2
- GGA2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs771058001, COSV59167678; called by muse, mutect2
- GGT1 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 36/642 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs201558016; called by muse, mutect2
- GLIS1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs144490309, COSV56547496; called by mutect2, varscan2
- GMPPA | c.498C>A p.H166Q | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1352913225; called by muse, mutect2
- GPR180 | c.9del p.L4_?3 | Frame Shift Del (DEL) | VAF 18/180 reads (10%) | catalogued as rs772740445; called by mutect2, pindel, varscan2
- GRIP1 | c.1633C>T p.R545* (on ENST00000359742 / NM_001379345.1; = p.R493* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/406 reads (9%) | catalogued as rs1452438437, COSV54021454; called by muse, mutect2
- HAO1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs763227029; called by muse, mutect2
- HDAC4 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as rs147050291; called by muse, mutect2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 18/158 reads (11%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HECTD4 | c.5923C>T p.R1975W | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66389252; called by muse, mutect2
- HELZ2 | c.6208G>A p.V2070I (on ENST00000467148 / NM_001037335.2; = p.V1501I on NM_033405.3) | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760698832; called by muse, mutect2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs1256699530; called by mutect2, pindel, varscan2
- HIC1 | c.179C>T p.A60V (on ENST00000322941 / NM_001098202.1; = p.A41V on NM_006497.4) | Missense Mutation (SNP) | VAF 23/331 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53971826; called by muse, mutect2
- ID3 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 27/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs934808402; called by muse, mutect2
- IGHA1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 36/1088 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.317); catalogued as rs587686108; called by muse, mutect2
- IGHA1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as rs766451356; called by muse, mutect2
- IKZF3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs778371145, COSV53108210; called by muse, mutect2
- ILDR2 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1429220005; called by muse, mutect2
- INPP5F | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs374196186; called by muse, mutect2
- INSRR | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 46/822 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753223410, COSV100948270, COSV63876504; called by muse, mutect2
- IRS4 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV64532834; called by muse, mutect2, varscan2
- IRX3 | c.1113del p.S372Lfs*151 | Frame Shift Del (DEL) | VAF 18/171 reads (11%) | catalogued as rs759120276; called by mutect2, pindel
- ITIH5 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs1247790056, COSV56906234; called by muse, mutect2
- JUP | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 24/597 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as rs199597864; ClinVar: uncertain significance; called by muse, mutect2
- KALRN | c.2855C>T p.T952M | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532130353, COSV53774491; called by muse, mutect2
- KAT6B | c.3763G>A p.G1255S | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.09); catalogued as rs147574112, COSV54744307; called by muse, mutect2
- KCNK13 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56411835; called by muse, mutect2
- KCNK3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV57192669; called by muse, mutect2
- KCNQ4 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 47/470 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs551509351; called by muse, mutect2, varscan2
- KCTD3 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as rs780870230; called by muse, mutect2, varscan2
- KDM6B | c.4667G>A p.R1556Q | Missense Mutation (SNP) | VAF 21/623 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV54684182, COSV54687792; called by muse, mutect2
- KIAA0753 | c.2737A>G p.I913V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1305713684; called by muse, mutect2
- KIF14 | c.4868A>G p.K1623R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100950993, COSV66264555; called by muse, mutect2, varscan2
- KIF1C | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1304103979; called by muse, mutect2, varscan2
- KIF20A | c.1210C>T p.L404= | Splice Region (SNP) | VAF 6/133 reads (5%) | catalogued as COSV54730425; called by muse, mutect2
- KLF4 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65929726; called by muse, mutect2
- KLHL4 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV64146214; called by muse, mutect2, varscan2
- KMT2A | c.4991G>A p.R1664Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs782779521, COSV100628365; called by muse, mutect2
- KMT2D | c.6700C>A p.P2234T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV56423055; called by muse, mutect2, varscan2
- KRT5 | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 39/494 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as rs759651620; called by muse, mutect2
- LAMA5 | c.4132G>A p.V1378M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs199705177; called by mutect2, varscan2
- LAMB1 | c.3497C>T p.T1166M | Missense Mutation (SNP) | VAF 36/470 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs771248391, COSV55962713; called by muse, mutect2
- LARGE1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1220026937; called by muse, mutect2
- LENG1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs111616066; called by muse, mutect2
- LILRA4 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs781507973; called by muse, mutect2
- LMNTD2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 23/306 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374252641; called by muse, mutect2
- LRFN1 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456565087; called by muse, mutect2
- LRRC29 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1452925447; called by muse, mutect2
- LRRC59 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); catalogued as rs751372015, COSV56813971; called by muse, mutect2
- LTN1 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs533578641; called by mutect2, varscan2
- LYRM4 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57993551, COSV57994394; called by muse, mutect2
- MANBA | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 33/581 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362274518; called by muse, mutect2
- MAP3K11 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV58420352; called by muse, mutect2, varscan2
- MAP3K19 | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs373039984; called by muse, mutect2
- MCM7 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs758673969; called by muse, mutect2, varscan2
- MEIOB | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1025418947; called by muse, mutect2
- METRN | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as COSV54801108; called by muse, mutect2
- METTL24 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.034); catalogued as rs952371913; called by muse, mutect2
- MFGE8 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 35/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs760298574, COSV51558228; called by muse, mutect2
- MMUT | c.2101T>C p.C701R | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as CD060617; called by muse, mutect2
- MROH5 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs371019146; called by muse, mutect2
- MS4A1 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs777874424, COSV100619449; called by muse, mutect2
- MS4A18 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs534337923, COSV67517736; called by muse, mutect2
- MUC16 | c.34931C>T p.T11644I | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.577); catalogued as rs866459974; called by muse, mutect2
- MXRA7 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 18/249 reads (7%) | PolyPhen possibly damaging (0.581); catalogued as rs1388582625; called by muse, mutect2
- MXRA8 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1322367962, COSV58510198; called by muse, mutect2
- MYH7 | c.5689C>T p.R1897C | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756655803, COSV62524771; called by muse, mutect2
- MYH9 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 38/601 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53392471, COSV53392490; called by muse, mutect2
- NAP1L3 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV59076801; called by muse, varscan2
- NEB | c.10657G>A p.A3553T | Missense Mutation (SNP) | VAF 37/547 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs749327025; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | catalogued as rs759081520; called by mutect2, varscan2
- NEU1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 52/620 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1263545300, COSV57666522; called by muse, mutect2
- NEURL1B | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs1420440418; called by muse, mutect2, varscan2
- NEUROG2 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100511859; called by muse, mutect2
- NID1 | c.3298C>T p.R1100W | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746516796, COSV51625828; called by muse, mutect2
- NKX2-2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 56/762 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65819876; called by muse, mutect2
- NLGN3 | c.713G>A p.R238Q (on ENST00000358741 / NM_181303.2; = p.R218Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104423798; called by muse, mutect2, varscan2
- NOCT | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs371556362; called by muse, mutect2
- NPHP4 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1270711258, COSV65395169; called by muse, mutect2, varscan2
- NUF2 | c.941T>C p.L314S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.468); catalogued as COSV54844592; called by muse, mutect2
- NUP133 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs373640878; called by muse, mutect2
- NXPE2 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64940637; called by muse, mutect2
- OBSCN | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 47/770 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52736812; called by muse, mutect2
- OR2L3 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100741936; called by muse, mutect2
- OR5K4 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs547691527; called by muse, mutect2
- OR9A4 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV71885570; called by muse, mutect2
- OR9I1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV56926412; called by muse, mutect2
- PAK6 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751329273; called by muse, mutect2
- PALB2 | c.2359A>G p.T787A | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1567217510; ClinVar: uncertain significance; called by muse, mutect2
- PAOX | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 28/453 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs771266490; called by muse, mutect2
- PAPPA | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV60291334; called by muse, mutect2
- PCDH11X | c.2570del p.P857Qfs*8 | Frame Shift Del (DEL) | VAF 31/282 reads (11%) | catalogued as COSV100014782; called by mutect2, pindel, varscan2
- PCDHA6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 44/712 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65342498; called by muse, mutect2
- PCDHAC1 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53850275; called by muse, mutect2
- PCDHB2 | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 33/844 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99164798; called by muse, mutect2
- PCDHB7 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.386); catalogued as rs782021995, COSV50793324; called by muse, mutect2
- PCDHGB1 | c.2122G>T p.A708S | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs749766771, COSV99547547; called by muse, mutect2
- PCLO | c.12815G>A p.R4272H | Missense Mutation (SNP) | VAF 26/411 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61658525; called by muse, mutect2
- PCLO | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs779246634; called by muse, mutect2
- PDZD4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1239111791; called by muse, mutect2, varscan2
- PENK | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV59242866; called by muse, mutect2
- PEX1 | c.1883A>G p.D628G | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99952235; called by muse, mutect2
- PIEZO1 | c.7189G>C p.A2397P | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as rs765524996; called by muse, mutect2
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 16/146 reads (11%) | catalogued as COSV56402935; called by mutect2, pindel
- PITPNM1 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs757915989; called by muse, mutect2
- PKDREJ | c.4033G>A p.V1345I | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs146200280, COSV53546483; called by muse, mutect2, varscan2
- PLEKHN1 | c.103T>A p.S35T | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs771316845; called by muse, mutect2
- PLXND1 | c.3920C>T p.T1307M | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1327363739; called by muse, mutect2
- PNMT | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99510550; called by muse, mutect2
- PNPLA1 | c.874C>T p.R292C (on ENST00000394571 / NM_001374623.1; = p.R197C on NM_173676.2) | Missense Mutation (SNP) | VAF 33/448 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs776818332, COSV100462918; called by muse, mutect2
- POGLUT2 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV65682799; called by muse, mutect2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 24/253 reads (9%) | catalogued as rs745933237; called by mutect2, pindel
- POMC | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53035169; called by muse, mutect2
- POMC | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV53034379; called by muse, mutect2
- PPAN-P2RY11 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.111); catalogued as rs771336005; called by muse, mutect2
- PPP2R3B | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as rs139187986, COSV101180781; called by muse, mutect2
- PRAMEF4 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 54/810 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs562920609, COSV52437653; called by muse, mutect2
- PRDM1 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV64847185; called by muse, mutect2
- PRORP | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as rs978666601, COSV51616493; called by muse, mutect2
- PRR23B | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 29/370 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs555725893, COSV61494422; called by muse, mutect2
- PRSS53 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs748276565, COSV99762675; called by muse, mutect2
- PRUNE2 | c.345T>C p.S115= | Splice Region (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100943164; called by muse, mutect2
- PTBP3 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99270372; called by muse, mutect2
- PTCD1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52868450; called by muse, mutect2
- PTCH1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 67/709 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs1293146883, COSV59492626; ClinVar: uncertain significance; called by muse, mutect2
- RAI1 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 81/968 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs780731931; called by muse, mutect2
- RAPSN | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 48/689 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs773316367; called by muse, mutect2
- RASGRF1 | c.625-2A>G p.X209_splice | Splice Site (SNP) | VAF 17/126 reads (13%) | catalogued as rs1247547616, COSV101369649; called by muse, varscan2
- RASSF7 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs761343590, COSV60346370, COSV60348461; called by muse, mutect2
- RECQL4 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1214615126; called by muse, mutect2, varscan2
- RELA | c.973del p.R325Gfs*31 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | catalogued as COSV58014620; called by mutect2, varscan2
- RFT1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 38/470 reads (8%) | catalogued as rs776522715; called by muse, mutect2
- RGL2 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs369642679; called by muse, mutect2
- RIMS2 | c.2458C>G p.Q820E (on ENST00000666250 / NM_001348490.2; = p.Q628E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51683094; called by muse, mutect2
- RIPOR3 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs756540695; called by muse, mutect2
- RNF11 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54376119; called by muse, mutect2
- RNF151 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs761528355; called by muse, mutect2
- ROBO3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 33/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM090354; called by muse, mutect2
- ROS1 | c.5743G>A p.G1915R | Missense Mutation (SNP) | VAF 37/420 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.383); catalogued as rs759091073, COSV63861219; called by muse, mutect2
- RTL4 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV61206723, COSV61207433; called by muse, mutect2, varscan2
- RTP5 | c.674del p.P225Lfs*8 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | catalogued as rs35989328, COSV100574622; called by mutect2, pindel
- RYR1 | c.6583C>T p.P2195S | Missense Mutation (SNP) | VAF 28/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62109024; called by muse, mutect2
- SCN4B | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 17/436 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1265062815, COSV61251899; called by muse, mutect2
- SDS | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV57452830; called by muse, mutect2
- SEMA3A | c.1227G>C p.M409I | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54880077; called by muse, mutect2
- SEMA4A | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV100740585; called by muse, mutect2, varscan2
- SEMA6B | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as rs1444539286; called by muse, mutect2
- SESN2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201255439; called by muse, mutect2, varscan2
- SETX | c.3143A>G p.Q1048R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs769702224; called by mutect2, varscan2
- SEZ6L | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); catalogued as rs1219092259; called by muse, varscan2
- SFSWAP | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 25/435 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1206172738, COSV104377397, COSV55525595; called by muse, mutect2
- SH3TC2 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs752002618, COSV60467211; called by muse, mutect2
- SIGLEC10 | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 30/688 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1231508879; called by muse, mutect2
- SKAP2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025140851, COSV61725796; called by muse, mutect2
- SKI | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 35/489 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs770481744; ClinVar: uncertain significance; called by muse, mutect2
- SLC25A19 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 31/612 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as rs758036010; called by muse, mutect2
- SLC25A22 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 49/746 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.671); catalogued as rs201932343; ClinVar: uncertain significance; called by muse, mutect2
- SLC25A27 | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64927959; called by muse, mutect2
- SLC25A29 | c.448G>A p.V150I (on ENST00000359232 / NM_001039355.3; = p.V84I on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs1448633005; called by muse, mutect2
- SLC26A3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1455672221; called by muse, mutect2
- SLC2A6 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs782059162; called by muse, mutect2
- SLC32A1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 38/678 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as rs1023170011, COSV54148411; called by muse, mutect2
- SLC5A11 | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs985662857, COSV100762808; called by muse, mutect2
- SLC6A11 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs1451859570; called by muse, mutect2
- SLCO1A2 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs937164998; called by muse, mutect2
- SLX4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 51/635 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs149779179; called by muse, mutect2
- SMARCA4 | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 50/608 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV60798787; called by muse, mutect2
- SNRNP200 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 38/431 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs750045583; called by muse, mutect2
- SORCS1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs780091835, COSV99544512; called by muse, mutect2
- SPRYD7 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 23/319 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1455808810, COSV62524021; called by muse, mutect2
- SPTA1 | c.2185C>T p.H729Y | Missense Mutation (SNP) | VAF 25/454 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1485723850; called by muse, mutect2
- SPTBN1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100776977; called by muse, mutect2
- SPTBN4 | c.6854G>A p.R2285H | Missense Mutation (SNP) | VAF 51/575 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.511); catalogued as rs540578822, COSV58948969; called by muse, mutect2
- SPTLC1 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV99364498; called by muse, mutect2, varscan2
- SRSF4 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs554229376; called by muse, mutect2
- STAC2 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 30/454 reads (7%) | catalogued as rs143497706; called by muse, mutect2
- STAG3 | c.3230G>A p.R1077H | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs768824588, COSV57927408; called by mutect2, varscan2
- STOX2 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1344767661; called by muse, mutect2
- SUPT6H | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1325940073; called by muse, mutect2
- TACR2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149007484; called by muse, mutect2, varscan2
- TAF1 | c.4600C>T p.R1534C (on ENST00000373790 / NM_138923.4; = p.R1555C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52124656; called by muse, mutect2, varscan2
- TAF4 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99433903; called by muse, mutect2
- TAL1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 15/356 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53745432; called by muse, mutect2
- TBX2 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1025055045; called by muse, mutect2
- TDRKH | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 27/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200284470, COSV64316321; called by muse, mutect2
- TGFBRAP1 | c.1032A>T p.K344N | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV51511886; called by muse, mutect2
- TLX3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 32/552 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766623983; called by muse, mutect2
- TMEM121 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555444261, COSV101180046; called by muse, mutect2
- TMEM132D | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.167); catalogued as rs1363837094; called by muse, mutect2
- TMEM200A | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775367537; called by muse, mutect2, varscan2
- TNFRSF11A | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 27/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763222674; called by muse, mutect2
- TNRC6A | c.3547del p.R1183Gfs*7 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1182016487; called by mutect2, varscan2
- TRIM42 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53880822, COSV53883667; called by muse, mutect2
- TRIM42 | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1309145653; called by muse, mutect2
- TRIOBP | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV60375355; called by muse, mutect2
- TRPC6 | c.2408A>G p.K803R | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.169); catalogued as rs750525727; called by mutect2, varscan2
- TSPAN16 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 35/502 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs750213552, COSV57441837; called by muse, mutect2
- TSPAN18 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 24/439 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV60887916; called by muse, mutect2
- TSPOAP1 | c.2267del p.G756Afs*23 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | catalogued as rs1463036794; called by mutect2, pindel, varscan2
- TTC21B | c.3545G>A p.R1182H | Missense Mutation (SNP) | VAF 38/556 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs199658616, COSV54627885; called by muse, mutect2
- TTC5 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as rs773124497, COSV51870906; called by muse, mutect2
- TTLL6 | c.1939A>G p.N647D (on ENST00000393382 / NM_001130918.3; = p.N340D on NM_173623.3) | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV64977146; called by muse, mutect2
- TTYH3 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.474); catalogued as rs772319940, COSV51860871; called by muse, mutect2
- TUBB6 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV52313891; called by mutect2, varscan2
- TXNRD3 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as rs763780159; called by muse, mutect2
- UBR7 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as rs779746473; called by muse, mutect2
- USH2A | c.10145T>C p.V3382A | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56375270; called by muse, mutect2
- USP21 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs781514698; called by muse, mutect2
- VARS1 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs762976775, COSV63304926; called by muse, mutect2
- VIM | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 45/650 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749084801, COSV56407465; called by muse, mutect2
- VPS51 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 64/692 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1316510985; called by muse, mutect2
- VSX2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1042589251; called by muse, mutect2
- WDFY4 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1256963585; called by muse, mutect2
- WDFY4 | c.4595G>A p.G1532D | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1323939717; called by muse, mutect2
- WDR62 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 48/468 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs752601653; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFIKKN1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1161349733, COSV50194119; called by muse, mutect2
- XPNPEP1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV100450952; called by muse, mutect2, varscan2
- ZC3H11A | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs1172582430, COSV59745578; called by muse, mutect2
- ZFHX4 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV50599698, COSV51505290; called by muse, mutect2
- ZNF208 | c.2891A>T p.K964M | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV68114748; called by muse, mutect2
- ZNF225 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs895745901; called by muse, mutect2
- ZNF239 | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as COSV100021670; called by muse, mutect2
- ZNF276 | c.631G>A p.G211R (on ENST00000443381 / NM_001113525.2; = p.G136R on NM_152287.4) | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs146286473; called by muse, mutect2
- ZNF385A | c.590C>T p.A197V (on ENST00000338010 / NM_001130967.3; = p.A177V on NM_015481.3) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233092399, COSV100566833; called by muse, mutect2
- ZNF410 | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs755285803; called by muse, mutect2
- ZNF513 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.031); catalogued as rs371030335; ClinVar: uncertain significance; called by muse, mutect2
- ZNF628 | c.724del p.Q242Sfs*185 | Frame Shift Del (DEL) | VAF 33/267 reads (12%) | catalogued as rs997975178; called by mutect2, pindel, varscan2
- ZNF629 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52697306; called by muse, mutect2
- ZNF680 | c.1252T>C p.C418R | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs1308175708; called by muse, mutect2
- ZNF831 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs754843638, COSV64038317; called by muse, mutect2, varscan2
- ZNF839 | c.2239G>A p.V747M (on ENST00000558850 / NM_001267827.1; = p.V863M on NM_018335.5) | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs746898107; called by muse, mutect2, varscan2
- AANAT | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ABCA1 | c.4103T>C p.V1368A | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2
- ABCA7 | c.5371del p.D1791Mfs*5 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- ACTBL2 | c.682A>G p.M228V | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.131); called by muse, mutect2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 17/130 reads (13%) | called by mutect2, varscan2
- ADCK5 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.957); called by muse, mutect2
- ADCY4 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2
- ADD2 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- ADH5 | c.744A>C p.K248N | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ADRA2B | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 45/546 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- AGFG1 | c.694+2T>C p.X232_splice | Splice Site (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- AHI1 | c.1101A>C p.K367N | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AHNAK | c.5129T>C p.L1710P | Missense Mutation (SNP) | VAF 29/573 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- AHNAK | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.187); called by muse, mutect2
- ALX1 | c.115T>A p.S39T | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); called by muse, mutect2
- ANKDD1A | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.057); called by muse, mutect2
- ANKRD26 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2
- ANKRD45 | c.381A>C p.K127N | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANTXRL | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP5Z1 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ARFGEF2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2
- ARHGAP45 | c.2937G>T p.E979D | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2
- ARMCX5-GPRASP2 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ART4 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- ATCAY | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 15/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP1A3 | c.2428A>G p.I810V (on ENST00000545399 / NM_001256214.2; = p.I797V on NM_152296.5) | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2
- B3GALT6 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- BACE2 | c.1426A>C p.M476L | Missense Mutation (SNP) | VAF 56/674 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- BAG3 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2
- BAHCC1 | c.1921A>G p.S641G | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- BAIAP3 | c.3296T>C p.V1099A | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.356); called by muse, mutect2
- BEST2 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- BRD2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.32); called by muse, mutect2
- BSG | c.416-3C>T | Splice Region (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- C16orf70 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- CABIN1 | c.4370C>T p.A1457V | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CACNA1D | c.6016T>C p.S2006P (on ENST00000350061 / NM_001128840.3; = p.S2026P on NM_000720.4) | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2
- CALU | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- CATSPERG | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- CBR3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- CBY3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.412); called by muse, mutect2
- CCDC8 | c.1439T>C p.F480S | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- CCDC8 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 45/685 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2
- CCDC88B | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); called by muse, mutect2
- CDK13 | c.3545C>T p.A1182V | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.235); called by muse, mutect2
- CFAP52 | c.754-1G>T p.X252_splice | Splice Site (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- CFLAR | c.337A>T p.I113F | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CHD5 | c.3903+1G>A p.X1301_splice | Splice Site (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CHD9 | c.5291A>G p.D1764G | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CHRD | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNB1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 74/788 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2
- CIITA | c.3125T>C p.L1042P | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLASP2 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- CLCA1 | c.519G>C p.E173D | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.41); called by muse, mutect2
- CLCA4 | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CNTN3 | c.2935G>T p.D979Y | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- CNTNAP2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 27/311 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2
- COL11A2 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.334); called by muse, mutect2
- COL12A1 | c.8677G>A p.G2893S | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- COL12A1 | c.4745T>C p.M1582T | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- COL18A1 | c.3706G>T p.G1236* (on ENST00000359759 / NM_130444.3; = p.G1001* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 34/404 reads (8%) | called by muse, mutect2
- COL18A1 | c.4660C>T p.H1554Y (on ENST00000359759 / NM_130444.3; = p.H1319Y on NM_030582.4) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2
- COL6A6 | c.5821T>C p.F1941L | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- COL7A1 | c.2467C>A p.P823T | Missense Mutation (SNP) | VAF 59/744 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.239); called by muse, mutect2
- CPLX2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2
- CREBBP | c.6355C>T p.P2119S | Missense Mutation (SNP) | VAF 48/668 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2
- CRHR2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CS | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 30/313 reads (10%) | called by muse, mutect2
- CXXC1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2
- CYP2D6 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 38/991 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CYP2E1 | c.713del p.N238Mfs*5 | Frame Shift Del (DEL) | VAF 9/91 reads (10%) | called by mutect2, pindel, varscan2
- CYP2W1 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DAG1 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 54/589 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DBP | c.925T>C p.S309P | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2
- DCHS2 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- DCP2 | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDAH1 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.239); called by muse, mutect2
- DDX60 | c.4164G>T p.K1388N | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DENND2D | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND3 | c.2881G>A p.V961I | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DIP2C | c.3899G>T p.R1300M | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DMBX1 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAH14 | c.415T>G p.C139G | Missense Mutation (SNP) | VAF 30/610 reads (5%) | called by muse, mutect2
- DOCK11 | c.2107C>T p.H703Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- DPAGT1 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 54/742 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- DROSHA | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- DRP2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.062); called by muse, mutect2
- E2F7 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.219); called by muse, mutect2
- EDA2R | c.671dup p.T225Dfs*2 | Frame Shift Ins (INS) | VAF 21/170 reads (12%) | called by mutect2, varscan2
- EDA2R | c.670delinsCC p.S224Pfs*3 | Frame Shift Ins (INS) | VAF 26/204 reads (13%) | called by mutect2*, pindel, varscan2*
- EDEM1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2
- EGF | c.3227G>T p.R1076I | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2
- EI24 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMILIN2 | c.2957G>A p.R986K | Missense Mutation (SNP) | VAF 49/486 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPB41L3 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- EPHA10 | c.2273T>C p.M758T | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ESAM | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EVA1B | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 54/740 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- EVC | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 48/630 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); called by muse, mutect2
- EVI5L | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- EXOC3L1 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2
- FAAP100 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- FABP7 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- FAM131C | c.661T>C p.C221R | Missense Mutation (SNP) | VAF 25/469 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- FAM135A | c.1524del p.K508Nfs*2 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- FAM184A | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 18/281 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM214A | c.818G>A p.W273* | Nonsense Mutation (SNP) | VAF 9/178 reads (5%) | called by muse, mutect2
- FAT4 | c.7076A>G p.D2359G | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXW2 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.772); called by muse, mutect2
- FETUB | c.436_437del p.K146Dfs*7 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, varscan2
- FFAR1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2
- FLII | c.2206G>T p.G736C | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLNA | c.3671T>C p.L1224P | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FNDC10 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.711); called by muse, mutect2
- FOXG1 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- FOXN3 | c.342A>C p.K114N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRYL | c.2963A>G p.E988G | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2
- FYCO1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2
- GABPB2 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GAS1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
- GDPGP1 | c.14A>T p.H5L | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.025); called by muse, mutect2
- GET3 | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- GFRA2 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- GFRA2 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.757); called by muse, mutect2
- GLT1D1 | c.528A>C p.Q176H | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- GMEB2 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 15/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GNAZ | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2
- GNL1 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, mutect2
- GNPNAT1 | c.162del p.F54Lfs*7 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, pindel, varscan2
- GP1BB | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 39/616 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- GPR75 | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2
- GRIN2C | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2
- GRIP2 | c.3382G>C p.A1128P (on ENST00000619221; = p.A1031P on NM_001080423.4) | Missense Mutation (SNP) | VAF 25/335 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- GRM3 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTPBP2 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- HAPLN3 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 48/831 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2
- HCFC1 | c.4292A>T p.H1431L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- HEATR5A | c.4705T>A p.F1569I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2
- HECA | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW1 | c.4187A>G p.D1396G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HELB | c.1661A>G p.H554R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.161); called by muse, mutect2
- HELT | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2
- HMCN2 | c.12604G>A p.A4202T | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HOXD11 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 27/510 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- HPF1 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HS6ST2 | c.1237A>G p.R413G | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HTRA4 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 39/658 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- HYOU1 | c.2515del p.A839Pfs*16 | Frame Shift Del (DEL) | VAF 26/285 reads (9%) | called by mutect2, pindel
- IGHG3 | c.1075C>A p.H359N | Missense Mutation (SNP) | VAF 58/722 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGSF1 | c.2971T>C p.C991R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ILDR2 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- INHBB | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.483); called by muse, mutect2
- IRGC | c.1102T>A p.F368I | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.159); called by muse, mutect2
- ITGA10 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- JAK3 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- JCAD | c.3964A>G p.K1322E | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- KALRN | c.4416G>T p.Q1472H | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- KATNIP | c.2770C>A p.L924M | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2
- KCNH1 | c.2711G>T p.S904I (on ENST00000271751 / NM_172362.3; = p.S877I on NM_002238.4) | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); called by muse, mutect2
- KCNK7 | c.719-1G>T p.X240_splice | Splice Site (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- KIAA2012 | c.1526del p.P509Rfs*31 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | called by mutect2, pindel, varscan2
- KIF1A | c.4001A>C p.E1334A (on ENST00000320389 / NM_001379639.1; = p.E1326A on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/488 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIRREL1 | c.547A>C p.S183R | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRBA1 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- KRT24 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP10-7 | c.734A>T p.D245V | Missense Mutation (SNP) | VAF 42/694 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- LAMB4 | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- LEMD2 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- LGR6 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- LHFPL3 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.212); called by muse, mutect2
- LHX4 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2
- LIG1 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 34/546 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- LPIN1 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 27/438 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2
- LRIF1 | c.786A>G p.I262M | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2
- LSR | c.1269del p.S424Vfs*8 (on ENST00000361790; = p.S405Vfs*8 on NM_015925.6) | Frame Shift Del (DEL) | VAF 13/150 reads (9%) | called by mutect2, pindel
- LTB | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 36/658 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LZTS3 | c.1448C>T p.S483L (on ENST00000329152; = p.S437L on NM_001282533.2) | Missense Mutation (SNP) | VAF 33/486 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.303); called by muse, mutect2
- MADD | c.4569G>T p.K1523N | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- MAGEC3 | c.1430T>A p.V477D | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- MAP3K10 | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.62); called by muse, mutect2
- MAPK7 | c.1361A>G p.Q454R | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.067); called by muse, mutect2
- MATR3 | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2
- MECOM | c.117C>A p.H39Q (on ENST00000468789 / NM_001105078.4; = p.H227Q on NM_004991.4) | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MED21 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- METTL18 | c.438A>G p.I146M | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- MIXL1 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- MLLT6 | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); called by muse, mutect2
- MPZL1 | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- MRC1 | c.2142G>A p.W714* | Nonsense Mutation (SNP) | VAF 25/393 reads (6%) | called by muse, mutect2
- MRPS5 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 35/597 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.218); called by muse, mutect2
- MTERF4 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 48/620 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYH13 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- MYH6 | c.1711A>C p.K571Q | Missense Mutation (SNP) | VAF 58/850 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); called by muse, mutect2
- MYO9B | c.1844A>G p.H615R | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NAP1L5 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- NCK2 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- NCKAP5L | c.3929C>A p.P1310H | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2
- NECTIN2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 21/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NELL2 | c.1850C>T p.T617I | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2
- NEURL4 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 31/419 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NOC2L | c.1967G>T p.R656M | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); called by muse, mutect2
- NOTCH2 | c.5478A>G p.P1826= | Splice Region (SNP) | VAF 18/294 reads (6%) | called by muse, mutect2
- NPHS1 | c.2872G>A p.G958R | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NSMAF | c.2638G>C p.E880Q | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2
- NTN4 | c.1395C>T p.S465= | Splice Region (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- NUDT18 | c.813T>A p.N271K | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- NUMA1 | c.5217-1G>A p.X1739_splice | Splice Site (SNP) | VAF 34/596 reads (6%) | called by muse, mutect2
- NUMA1 | c.4079T>G p.L1360R | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- NVL | c.2057T>C p.L686S | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ONECUT2 | c.1127A>G p.K376R | Missense Mutation (SNP) | VAF 42/537 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2
- OPA3 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2
- OR5AR1 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- OR7E24 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 21/306 reads (7%) | called by muse, mutect2
- OSBPL5 | c.383T>A p.I128N | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PCDHB10 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 23/333 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- PCK2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- PCLO | c.10720G>C p.D3574H | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2
- PCNX2 | c.788A>G p.Q263R | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PDE1B | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PDK1 | c.1006T>C p.Y336H | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEX5L | c.1259G>T p.W420L | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGR | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.14); called by muse, mutect2
- PGR | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- PHF1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PI4KA | c.5577G>A p.M1859I | Missense Mutation (SNP) | VAF 26/427 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- PID1 | c.643A>G p.M215V (on ENST00000354069 / NM_001330156.1; = p.M213V on NM_017933.5) | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- PLEKHM1 | c.1025A>G p.H342R | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- PLPPR4 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- PLXNA2 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); called by muse, mutect2
- PMP22 | c.23T>G p.I8S | Missense Mutation (SNP) | VAF 54/724 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2
- POTEC | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- POU2AF1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.427); called by muse, mutect2
- PRAMEF27 | c.1363T>G p.F455V | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PRDM13 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 25/388 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); called by muse, mutect2
- PROSER3 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- PRR14L | c.3146C>T p.T1049I | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- PRSS12 | c.1428C>G p.S476R | Missense Mutation (SNP) | VAF 29/401 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2
- PSME4 | c.4403T>C p.L1468P | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PTN | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2
- PTPN6 | c.843C>A p.P281= | Splice Region (SNP) | VAF 34/420 reads (8%) | called by muse, mutect2
- PTPRQ | c.417T>A p.C139* (on ENST00000616559; = p.C97* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PTPRU | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- RAB6C | c.376A>G p.N126D | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAD54L2 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 34/562 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2
- RAPGEF3 | c.2072T>C p.L691P (on ENST00000389212; = p.L649P on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- RAPGEF3 | c.1903C>T p.P635S (on ENST00000389212; = p.P593S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- RASGRF2 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2
- RASGRF2 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- RECQL4 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- RFX2 | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.405); called by muse, varscan2
- RGS22 | c.378del p.E127Kfs*17 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel
- RHCE | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2
- RIC1 | c.3526A>G p.N1176D | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2
- RMC1 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- RNF44 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2
- ROS1 | c.5579C>A p.T1860K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.551); called by muse, varscan2
- RPAP3 | c.1566C>G p.Y522* | Nonsense Mutation (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- RPL19 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- RPS27L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 30/456 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2
- SALL3 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 33/524 reads (6%) | called by muse, mutect2
- SAT2 | c.365G>A p.C122Y | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCYL1 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.241); called by muse, mutect2
- SETD2 | c.6060+2T>G p.X2020_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | called by muse, varscan2
- SETDB1 | c.2513C>T p.T838I | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SF3B1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SFRP2 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SGSH | c.664-2A>G p.X222_splice | Splice Site (SNP) | VAF 36/294 reads (12%) | called by muse, mutect2, varscan2
- SH2B1 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SH3PXD2B | c.563-2A>G p.X188_splice | Splice Site (SNP) | VAF 34/608 reads (6%) | called by muse, mutect2
- SIM1 | c.998+1G>A p.X333_splice | Splice Site (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- SIN3B | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIPA1 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SKIV2L | c.242G>A p.W81* | Nonsense Mutation (SNP) | VAF 23/294 reads (8%) | called by muse, mutect2
- SLC19A2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 37/408 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- SLC22A7 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2
- SLC25A6 | c.851del p.G284Afs*14 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | called by mutect2, pindel
- SLC26A3 | c.1852C>A p.Q618K | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.122); called by muse, mutect2
- SLC28A1 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 48/732 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2
- SLC46A2 | c.932A>G p.E311G | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2
- SLC47A1 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.122); called by muse, mutect2
- SLC5A3 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2
- SLC8A2 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMTN | c.1297C>G p.P433A | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOS2 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2
- SOWAHB | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2
- SOX10 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 40/618 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- SOX21 | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 56/957 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2
- SP3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 37/488 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2
- SP9 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2
- SPHKAP | c.3439C>G p.L1147V | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPINT1 | c.944A>G p.Q315R | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- SPRYD7 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2
- SSTR3 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- STAU2 | c.1055C>T p.T352I (on ENST00000524300 / NM_001164380.2; = p.T320I on NM_014393.2) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.869); called by muse, mutect2
- STON1 | c.1229A>T p.Y410F | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); called by muse, mutect2
- STON1 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2
- STRA8 | c.86A>G p.N29S (on ENST00000275764; = p.N7S on NM_182489.2) | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- SURF2 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.092); called by muse, mutect2
- SYTL2 | c.1760G>A p.S587N (on ENST00000528231 / NM_001162951.2; = p.S1876N on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2
- TACSTD2 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TACSTD2 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2
- TADA1 | c.858G>A p.V286= | Splice Region (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- TAP2 | c.844T>C p.Y282H | Missense Mutation (SNP) | VAF 68/1049 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2
- TATDN2 | c.1351T>C p.S451P | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- TBCE | c.667G>A p.D223N (on ENST00000366601; = p.D286N on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2
- TBX19 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 44/690 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- THUMPD1 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TIMM44 | c.395G>T p.S132I | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.065); called by muse, mutect2
- TLR9 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); called by muse, mutect2
- TM6SF1 | c.1007del p.L336* | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- TMC8 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 44/470 reads (9%) | called by muse, mutect2
- TMEM121B | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- TMEM169 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 60/769 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2
- TMEM240 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); called by muse, mutect2
- TMEM255A | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM8B | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TNRC18 | c.3746T>G p.L1249R | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2
- TPM2 | c.493-1G>T p.X165_splice | Splice Site (SNP) | VAF 63/934 reads (7%) | called by muse, mutect2
- TRAJ13 | c.13del p.G5Vfs*? | Frame Shift Del (DEL) | VAF 14/153 reads (9%) | called by mutect2, pindel
- TRANK1 | c.5735T>C p.L1912P | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAPPC5 | c.325A>G p.N109D | Missense Mutation (SNP) | VAF 31/494 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); called by muse, mutect2
- TRAPPC6A | c.442C>T p.P148S (on ENST00000585934 / NM_001270891.2; = p.P162S on NM_024108.3) | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRBV29-1 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 29/433 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM62 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 35/626 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2
- TSPYL6 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2
- TTC7A | c.2417T>C p.V806A | Missense Mutation (SNP) | VAF 32/483 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- TTLL4 | c.1925G>A p.G642D | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UBR4 | c.14255A>G p.E4752G | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- UNC80 | c.479A>C p.Q160P | Missense Mutation (SNP) | VAF 33/448 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- USP17L7 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 70/498 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.124); called by muse, varscan2
- USP40 | c.2027T>C p.V676A | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); called by muse, mutect2
- VARS1 | c.2650-1G>T p.X884_splice | Splice Site (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- VPS9D1 | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- WDR76 | c.60+5G>C | Splice Region (SNP) | VAF 22/392 reads (6%) | called by muse, mutect2
- WRNIP1 | c.1426A>G p.I476V | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2
- XCR1 | c.886A>G p.T296A | Missense Mutation (SNP) | VAF 50/502 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- ZNF219 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF248 | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF26 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2
- ZNF287 | c.1585dup p.I529Nfs*9 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, pindel, varscan2
- ZNF292 | c.5861G>A p.C1954Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF324B | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 27/405 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- ZNF560 | c.1309T>C p.C437R | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF575 | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF696 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2
- ZNF704 | c.409A>G p.S137G | Missense Mutation (SNP) | VAF 40/477 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZNF875 | c.1328G>A p.C443Y | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNRF3 | c.1000C>T p.R334W (on ENST00000544604 / NM_001206998.2; = p.R234W on NM_032173.3) | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZSCAN26 | c.875A>C p.Q292P (on ENST00000623276 / NM_001111039.2; = p.Q158P on NM_152736.5) | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ACOX2 | c.351T>C p.N117= | Silent (SNP) | VAF 17/226 reads (8%) | called by muse, mutect2
- ACTR6 | c.627A>G p.V209= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ADAM8 | c.432T>C p.D144= | Silent (SNP) | VAF 23/306 reads (8%) | called by muse, mutect2
- ADAMTSL4 | c.1413T>C p.P471= | Silent (SNP) | VAF 48/596 reads (8%) | called by muse, mutect2
- ADCY8 | c.858G>A p.P286= | Silent (SNP) | VAF 19/458 reads (4%) | catalogued as COSV99654535; called by muse, mutect2
- ADGRE5 | c.435G>A p.L145= | Silent (SNP) | VAF 26/641 reads (4%) | called by muse, mutect2
- ADRB3 | c.312G>A p.P104= | Silent (SNP) | VAF 41/492 reads (8%) | called by muse, mutect2
- AGER | c.1098G>A p.R366= | Silent (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- AGXT2 | c.393C>T p.L131= | Silent (SNP) | VAF 48/657 reads (7%) | catalogued as rs758853262, COSV51485327; called by muse, mutect2
- AHNAK | c.15525C>T p.I5175= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as rs775706270; called by muse, mutect2
- AHR | c.1416T>G p.A472= | Silent (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- AKR1D1 | c.783T>G p.R261= | Silent (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- ARID1A | c.1032T>A p.A344= | Silent (SNP) | VAF 6/103 reads (6%) | called by muse, mutect2
- ATP12A | c.2133G>A p.Q711= | Silent (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- BARHL2 | c.528C>T p.N176= | Silent (SNP) | VAF 52/897 reads (6%) | catalogued as COSV64980975; called by muse, mutect2
- BCAR1 | c.1512G>A p.L504= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as rs1370516321; called by muse, mutect2
- BHLHE41 | c.540G>A p.L180= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- BSX | c.123C>T p.F41= | Silent (SNP) | VAF 16/278 reads (6%) | catalogued as rs1220425761, COSV58005458; called by muse, mutect2
- BTBD18 | c.415C>T p.L139= | Silent (SNP) | VAF 21/265 reads (8%) | called by muse, mutect2
- C11orf42 | c.174A>G p.P58= | Silent (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- C19orf67 | c.84G>A p.T28= | Silent (SNP) | VAF 44/482 reads (9%) | catalogued as COSV99513790; called by muse, mutect2
- CACNG5 | c.159C>A p.S53= | Silent (SNP) | VAF 21/210 reads (10%) | called by muse, mutect2
- CARD9 | c.1089G>A p.T363= | Silent (SNP) | VAF 12/225 reads (5%) | catalogued as rs1217807819; called by muse, mutect2
- CCDC116 | c.835T>C p.L279= | Silent (SNP) | VAF 24/468 reads (5%) | catalogued as COSV53038730; called by muse, mutect2
- CCDC60 | c.888G>A p.L296= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as COSV59549460; called by muse, mutect2
- CCSAP | c.582C>T p.T194= | Silent (SNP) | VAF 18/255 reads (7%) | catalogued as rs777028561; called by muse, mutect2
- CDH22 | c.1734C>T p.P578= | Silent (SNP) | VAF 30/382 reads (8%) | catalogued as COSV100952629; called by muse, mutect2
- CDHR5 | c.1974G>A p.S658= (on ENST00000358353 / NM_001171968.2; = p.S664= on NM_021924.5) | Silent (SNP) | VAF 33/339 reads (10%) | catalogued as rs567663410; called by muse, mutect2, varscan2
- CELSR1 | c.4242C>T p.N1414= | Silent (SNP) | VAF 25/440 reads (6%) | catalogued as rs374497127, COSV53102242; called by muse, mutect2
- CELSR3 | c.1380C>T p.G460= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs1480603299; called by muse, mutect2
- CHD7 | c.321C>T p.T107= | Silent (SNP) | VAF 43/590 reads (7%) | catalogued as rs571544655; called by muse, mutect2
- CIAO2B | c.15C>T p.G5= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs950590013; called by muse, mutect2
- CLDN10 | c.81C>T p.T27= | Silent (SNP) | VAF 29/457 reads (6%) | called by muse, mutect2
- CLTCL1 | c.2409C>T p.Y803= | Silent (SNP) | VAF 9/156 reads (6%) | catalogued as rs556351450; called by muse, mutect2
- COL4A1 | c.2376C>T p.S792= | Silent (SNP) | VAF 34/446 reads (8%) | catalogued as rs535938031, COSV65422537; called by muse, mutect2
- COL9A1 | c.798C>T p.D266= | Silent (SNP) | VAF 27/858 reads (3%) | called by muse, mutect2
- CPN1 | c.129C>T p.P43= | Silent (SNP) | VAF 54/703 reads (8%) | catalogued as rs779001062; called by muse, mutect2
- CPNE1 | c.1068C>A p.A356= (on ENST00000352393; = p.A361= on NM_003915.5) | Silent (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- CRB2 | c.1200C>T p.C400= | Silent (SNP) | VAF 25/302 reads (8%) | called by muse, mutect2
- CREBBP | c.123T>C p.P41= | Silent (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
- CST3 | c.174C>T p.G58= | Silent (SNP) | VAF 38/459 reads (8%) | catalogued as rs766473502; called by muse, mutect2
- CYP21A2 | c.234T>C p.I78= | Silent (SNP) | VAF 40/701 reads (6%) | called by muse, mutect2
- CYP2W1 | c.501G>A p.P167= | Silent (SNP) | VAF 11/188 reads (6%) | catalogued as rs1201737090; called by muse, mutect2
- CYP3A4 | c.1506A>G p.T502= (on ENST00000336411; = p.T471= on NM_017460.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- DCAKD | c.108G>A p.R36= | Silent (SNP) | VAF 21/219 reads (10%) | called by muse, mutect2
- DGAT2 | c.723G>A p.A241= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs754872194, COSV57175216; called by mutect2, varscan2
- DHX34 | c.2220G>A p.R740= | Silent (SNP) | VAF 25/293 reads (9%) | catalogued as rs770385779; called by muse, mutect2
- DMRT2 | c.1350T>C p.H450= | Silent (SNP) | VAF 22/335 reads (7%) | called by muse, mutect2
- DNAH5 | c.11151T>C p.T3717= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- DNHD1 | c.10113C>A p.A3371= | Silent (SNP) | VAF 36/620 reads (6%) | called by muse, mutect2
- DPEP1 | c.282C>T p.A94= | Silent (SNP) | VAF 46/598 reads (8%) | catalogued as rs772353636; called by muse, mutect2
- DSC1 | c.2478G>A p.R826= | Silent (SNP) | VAF 13/212 reads (6%) | catalogued as COSV57147439; called by muse, mutect2
- DUSP21 | c.307C>T p.L103= | Silent (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- ECE1 | c.1926C>T p.T642= | Silent (SNP) | VAF 31/428 reads (7%) | catalogued as rs562954137, COSV99942410; called by muse, mutect2
- EHD2 | c.645C>T p.R215= | Silent (SNP) | VAF 13/206 reads (6%) | catalogued as rs1043214730, COSV54411427; called by muse, mutect2
- ELANE | c.441C>T p.N147= | Silent (SNP) | VAF 40/526 reads (8%) | catalogued as rs146878885; called by muse, mutect2
- ELOB | c.333T>C p.S111= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as rs909697699; called by muse, mutect2
314 further variants in this file (0 protein-altering or splice-affecting, 191 silent, 123 other) are not listed here.
